Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A1BF, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A1BF-01B (Primary Tumor).

125-0-3

Carcinoma, squamous cell, Nos 8070/3

Site Code: Cervix, Nos C53.9

12/29/10
lw

OF SURGICAL PATHOLOGY

Name: [REDACTED]
Address: [REDACTED]
MR No.: [REDACTED]
Service: GYNECOLOGY
Surgeon: [REDACTED]

Surg. Path. No.: [REDACTED]
DOB: [REDACTED]
Sex/Race: F UNKNOWN
Location: [REDACTED]
Hosp. No.: [REDACTED]
Taken/Received: [REDACTED]

DIAGNOSIS

UTERUS, CERVIX, BIOPSY - INVASIVE SQUAMOUS CELL CARCINOMA

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis), and that I have reviewed and approved this report.

SPECIMEN(S) SUBMITTED

CERVIX

HISTORY

The patient is a [REDACTED] year old woman who has a high grade squamous lesion on a PAP smear of [REDACTED] Operative procedure: Cervical biopsy.

GROSS

The specimen is received in a container of formalin, labelled with the patient's name and "cervical biopsy." It consists of multiple soft, friable fragments of tan to tan-brown tissue that in aggregate measure 1.1 x 0.6 x 0.3 cm. The largest tissue fragment has a greatest dimension of 0.3 cm. Wrapped in tissue paper. Jar 0.

COMMENT

Sections show a well differentiated invasive squamous cell carcinoma. Focal areas of keratinization are present. A prominent eosinophilic infiltrate accompanies the tumor.

Case in Circle:		

Source: NCI Genomic Data Commons file 0a04411a-4d11-413f-91c9-0675b9edf6b4 (TCGA-C5-A1BF.45EC2A51-EDE1-44E9-8756-A094B998A68B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).